Somatic mutation profile of tumor specimen TCGA-P3-A5QE-01A (aliquot TCGA-P3-A5QE-01A-11D-A28R-08) from TCGA case TCGA-P3-A5QE, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 49.3 years (18,002 days).
Specimen TCGA-P3-A5QE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5da7d527-ef3b-451d-a668-df44a929f5ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A5QE-10A (Blood Derived Normal), aliquot TCGA-P3-A5QE-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/046eff1d-5af9-44cd-976b-3f95a44bd06f

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Nonsense Mutation 3, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.372G>C p.L124F | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99797339; called by muse, mutect2, varscan2
- AKAP13 | c.6026A>G p.H2009R (on ENST00000394518 / NM_007200.5; = p.H2013R on NM_006738.6) | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774873; called by muse, mutect2, varscan2
- CACNA1C | c.2068G>T p.D690Y | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100223336, COSV59738660; called by muse, mutect2, varscan2
- CBFA2T2 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100656568; called by muse, mutect2
- CCDC88C | c.4562C>G p.S1521* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100485095; called by muse, mutect2, varscan2
- CDC25B | c.950G>A p.R317Q (on ENST00000245960 / NM_021873.3; = p.R303Q on NM_004358.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.403); catalogued as rs1240598537, COSV55659306; called by muse, mutect2, varscan2
- CDIP1 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV99566739; called by muse, mutect2
- CLN8 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.318); catalogued as rs143701028; called by muse, mutect2, varscan2
- CNTFR | c.491G>T p.C164F | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63634696; called by muse, mutect2, varscan2
- CYLD | c.1094C>G p.S365* | Nonsense Mutation (SNP) | VAF 19/39 reads (49%) | catalogued as COSV61094598, COSV61094741; called by muse, mutect2, varscan2
- DHX33 | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99834548; called by muse, mutect2, varscan2
- EHD2 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs749802863, COSV99622307; called by muse, mutect2, varscan2
- EIF1B | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as rs1201220514, COSV99233827; called by muse, mutect2, varscan2
- EMILIN2 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs764459073, COSV54424949; called by muse, mutect2, varscan2
- ENTHD1 | c.467T>C p.L156S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100289244; called by muse, mutect2, varscan2
- GJA5 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs906244249, COSV54786303; called by muse, mutect2, varscan2
- HLA-DQA2 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100890782, COSV100890817; called by muse, mutect2, varscan2
- JAK1 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs944169508, COSV100692570, COSV61095323; called by muse, mutect2, varscan2
- LTBR | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 92/287 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs541718272, COSV57438230; called by muse, mutect2, varscan2
- MSLN | c.699del p.Y234Tfs*78 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | catalogued as rs1304207931; called by mutect2, varscan2
- OR51M1 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs776850628, COSV60785098; called by muse, mutect2, varscan2
- PHKA2 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101177412, COSV101177639; called by muse, mutect2, varscan2
- SCN3B | c.307G>A p.V103M | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.852); catalogued as rs1369842400, COSV100173905; called by muse, mutect2, varscan2
- SECISBP2 | c.2189A>T p.N730I | Missense Mutation (SNP) | VAF 92/282 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100358930; called by muse, mutect2, varscan2
- TEAD2 | c.76G>T p.G26C | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV99678840; called by muse, mutect2, varscan2
- TFAP2C | c.159A>T p.E53D | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1228484354, COSV99571856; called by muse, mutect2, varscan2
- THAP4 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.279); catalogued as COSV101126115; called by muse, mutect2, varscan2
- TRAM1L1 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.864); catalogued as COSV100162413; called by muse, mutect2, varscan2
- TRIM23 | c.1036T>G p.L346V | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.076); catalogued as COSV99140332; called by muse, mutect2, varscan2
- TTC31 | c.679G>C p.E227Q | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV99282434; called by muse, mutect2, varscan2
- USP34 | c.9460C>T p.R3154* | Nonsense Mutation (SNP) | VAF 4/56 reads (7%) | catalogued as COSV101277292; called by muse, mutect2
- IFT140 | c.3713C>G p.A1238G | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT26 | c.418_421del p.V140* | Frame Shift Del (DEL) | VAF 27/97 reads (28%) | called by mutect2, pindel, varscan2
- ANKMY1 | c.1962G>A p.P654= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs776684057, COSV99803531; called by muse, mutect2, varscan2
- ARHGAP22 | c.1305G>A p.P435= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs773574521, COSV99986206; called by muse, varscan2
- ARVCF | c.903C>T p.Y301= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs781656836, COSV54271188; called by muse, mutect2, varscan2
- KRT17 | c.72G>A p.S24= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs536792008, COSV60860541; called by muse, mutect2, varscan2
- OR8B3 | c.645C>T p.L215= | Silent (SNP) | VAF 52/159 reads (33%) | catalogued as rs760527623, COSV100660442; called by muse, mutect2, varscan2
- QRICH2 | c.4587C>T p.H1529= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs760270586, COSV99428730; called by muse, mutect2, varscan2
- QSOX2 | c.1734C>T p.S578= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV100699893; called by muse, mutect2, varscan2
- TBX15 | c.1596G>A p.P532= (on ENST00000369429 / NM_001330677.2; = p.P426= on NM_152380.3) | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs574411651, COSV99254681; called by muse, mutect2, varscan2
- TDRD5 | c.135C>G p.L45= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV99677470; called by muse, mutect2, varscan2
- AK5 | c.699+15875C>T | Intron (SNP) | VAF 11/38 reads (29%) | catalogued as COSV100481589; called by muse, mutect2, varscan2
